Surgical pathology report (de-identified scan), TCGA case TCGA-4G-AAZT, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Sapienza University of Rome, specimen TCGA-4G-AAZT-01A (Primary Tumor).

pathology report

Date of tumor procurement:

Anatomic site: intrahepatic

Histology diagnosis: moderately differentiated intrahepatic cholangiocarcinoma

Immunohistochemistry: CK7 positive, CK20 , CDX2 and TTF1 negative

Histological examination:

Liver: resected parenchyma of 14x10 cm containing a whitish nodule of 9.2 cm, located 1.4 cm distant from the resection margin. Histologically it is a moderately differentiated adenocarcinoma with an immunohistochemical profile consistent with intrahepatic cholangiocarcinoma with positivity for cytokeratin 7 and negative for cytokeratin 20, CDX2 and TTF1. The liver tissue shows mild steatosis (<5%) associated with mild fibrosis.

Reactive lymphadenitis in all the examined lymph nodes: hepatic artery lymph nodes (2), retrocardial lymph node (1), retro portal lymph nodes (2), inter aorto-caval lymph nodes (3).

ICD O 3
Cholangiocarcinoma 8160/3
Site: Intrahepatic bile duct C22.1
JW 4/22/14

Source: NCI Genomic Data Commons file 14376914-9242-4e16-85e9-92c4194c90a1 (TCGA-4G-AAZT.C75C91FD-D4DE-4A58-A4C7-8F020AAC59EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).